Somatic mutation profile of tumor specimen ALCH-B39F-TTP1-A (aliquot ALCH-B39F-TTP1-A-2-0-D-A799-36) from ALCHEMIST case ALCH-B39F, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 80.6 years (29,427 days).
Specimen ALCH-B39F-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5509d0c-7df1-4f67-97fe-3816e7aaf7ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B39F-NB1-A (Blood Derived Normal), aliquot ALCH-B39F-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe241a26-4580-4b7d-abc6-b9f5cdf69234

The open-access MAF lists 478 somatic variants for this specimen: 327 protein-altering or splice-affecting, 93 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 284, Silent 93, Intron 24, Nonsense Mutation 17, 3'UTR 12, 5'UTR 11, Frame Shift Del 11, Splice Site 8, RNA 7, Splice Region 4, 5'Flank 3, Frame Shift Ins 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CUL7 | c.1648C>T p.R550* | Nonsense Mutation (SNP) | VAF 33/259 reads (13%) | catalogued as rs746333044, COSV54816389; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.2453del p.G818Vfs*8 | Frame Shift Del (DEL) | VAF 118/898 reads (13%) | catalogued as rs587778837, COSV57295299, COSV57325282; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA7 | c.2740del p.A914Lfs*2 | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | catalogued as COSV54030858; called by mutect2, pindel, varscan2
- AFF3 | c.1865del p.P622Rfs*24 | Frame Shift Del (DEL) | VAF 21/97 reads (22%) | catalogued as COSV100420164; called by mutect2, pindel, varscan2
- ANK2 | c.4732G>C p.V1578L | Missense Mutation (SNP) | VAF 31/317 reads (10%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as COSV52177782; called by muse, mutect2
- ATP6V1B2 | c.700A>G p.M234V | Missense Mutation (SNP) | VAF 46/357 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV52354513; called by muse, mutect2, varscan2
- BRIP1 | c.2960G>C p.R987T | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT tolerated, low confidence (0.32); PolyPhen probably damaging (1); catalogued as COSV52009378; called by muse, mutect2, varscan2
- C11orf97 | c.376A>G p.R126G | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.3); catalogued as rs1218959866; called by muse, mutect2, varscan2
- CABP7 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs988904990, COSV53362935; called by muse, mutect2, varscan2
- CAMSAP1 | c.3427C>T p.R1143W | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as rs754996427, COSV56722221; called by muse, mutect2, varscan2
- CCDC178 | c.1303G>A p.V435I | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV55778202; called by muse, mutect2
- CCDC85A | c.1576G>T p.V526L | Missense Mutation (SNP) | VAF 40/639 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs550180400; called by muse, mutect2
- CCM2L | c.1623C>G p.I541M | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1228665752; called by muse, mutect2, varscan2
- CD300C | c.425C>G p.P142R | Missense Mutation (SNP) | VAF 59/373 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV58169639; called by muse, mutect2, varscan2
- CDH20 | c.1087C>A p.R363S | Missense Mutation (SNP) | VAF 53/461 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as rs1427688843, COSV99405962; called by muse, mutect2, varscan2
- CDV3 | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 66/426 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs760183626; called by muse, mutect2, varscan2
- CFAP47 | c.402-1G>T p.X134_splice | Splice Site (SNP) | VAF 39/292 reads (13%) | catalogued as COSV52885315, COSV99935765; called by muse, mutect2, varscan2
- CFAP47 | c.8357C>T p.P2786L | Missense Mutation (SNP) | VAF 46/314 reads (15%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.012); catalogued as rs781908471; called by muse, mutect2, varscan2
- CHRFAM7A | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 32/450 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.218); catalogued as rs368423557; called by muse, mutect2
- CNTLN | c.3886C>T p.H1296Y | Missense Mutation (SNP) | VAF 55/290 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs764374069; called by muse, mutect2, varscan2
- CNTNAP5 | c.1219A>T p.T407S | Missense Mutation (SNP) | VAF 51/736 reads (7%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.997); catalogued as COSV101443122; called by muse, mutect2
- COL16A1 | c.3211C>T p.R1071* | Nonsense Mutation (SNP) | VAF 23/158 reads (15%) | catalogued as rs368967625; called by muse, mutect2, varscan2
- COL17A1 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 89/862 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62229873; called by muse, mutect2, varscan2
- COL9A3 | c.368C>A p.P123H | Missense Mutation (SNP) | VAF 43/304 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as COSV59653895; called by muse, mutect2, varscan2
- CSMD1 | c.7769G>T p.S2590I (on ENST00000520002; = p.S2589I on NM_033225.6) | Missense Mutation (SNP) | VAF 39/308 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV59385313; called by muse, mutect2, varscan2
- CYP11B2 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 51/314 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs377560888, CM087151; called by muse, mutect2, varscan2
- DHX37 | c.2669G>A p.R890H | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1214952529; called by muse, mutect2, varscan2
- DLL1 | c.1489C>A p.H497N | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1238908942; called by muse, mutect2, varscan2
- EEF2K | c.1590G>T p.M530I | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); catalogued as COSV99533533; called by muse, mutect2, varscan2
- ENGASE | c.979G>C p.V327L | Missense Mutation (SNP) | VAF 23/325 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs774118597, COSV56134651; called by muse, mutect2
- EPHX3 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 42/222 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.892); catalogued as rs775153077; called by muse, mutect2, varscan2
- EPS8L3 | c.1649C>A p.T550K (on ENST00000361965 / NM_133181.4; = p.T520K on NM_024526.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as rs1053382995; called by muse, mutect2, varscan2
- ERLEC1 | c.1036C>G p.R346G | Missense Mutation (SNP) | VAF 32/718 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs778793766, COSV51751194; called by muse, mutect2
- FAM47A | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.579); catalogued as rs1304387328, COSV60498436, COSV60500315; called by muse, mutect2, varscan2
- FAM9A | c.73C>A p.Q25K | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.019); catalogued as COSV66813374; called by muse, mutect2
- FLG | c.10970G>A p.R3657Q | Missense Mutation (SNP) | VAF 137/842 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.045); catalogued as rs201687214; called by muse, mutect2, varscan2
- FREM2 | c.7652-1G>T p.X2551_splice | Splice Site (SNP) | VAF 41/232 reads (18%) | catalogued as COSV99745947; called by muse, mutect2, varscan2
- GABRA4 | c.1303C>A p.P435T | Missense Mutation (SNP) | VAF 52/415 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.572); catalogued as COSV51936488; called by muse, mutect2, varscan2
- GAS1 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.828); catalogued as rs774972884; called by muse, mutect2
- GPR119 | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 24/155 reads (15%) | catalogued as COSV52276702; called by muse, mutect2, varscan2
- GPR52 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 12/359 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV52331969; called by muse, mutect2
- GPR63 | c.1121G>C p.R374T | Missense Mutation (SNP) | VAF 72/442 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV57742703; called by muse, mutect2, varscan2
- GYG2 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 31/295 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100088735; called by muse, mutect2
- HGF | c.506del p.G169Vfs*44 | Frame Shift Del (DEL) | VAF 74/522 reads (14%) | catalogued as COSV55958402; called by mutect2, pindel, varscan2
- HSPA13 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 43/389 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53466663; called by muse, mutect2, varscan2
- IL23R | c.-29-1G>T | Splice Site (SNP) | VAF 55/339 reads (16%) | catalogued as COSV61375548; called by muse, mutect2, varscan2
- IRAG1 | c.90G>A p.W30* | Nonsense Mutation (SNP) | VAF 35/292 reads (12%) | catalogued as rs1332778592; called by muse, mutect2, varscan2
- ISG20 | c.512G>T p.R171L | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV60144092, COSV60145067; called by muse, mutect2, varscan2
- KAT2B | c.1339G>T p.G447W | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV55430598; called by muse, mutect2, varscan2
- KCNK9 | c.940C>A p.P314T | Missense Mutation (SNP) | VAF 38/491 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as COSV57278490; called by muse, mutect2
- KIF6 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99761184; called by muse, mutect2, varscan2
- LARP1B | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52794994; called by muse, mutect2
- LGR4 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.955); catalogued as COSV64864728; called by muse, mutect2, varscan2
- LHFPL1 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100914531; called by muse, mutect2
- LPA | c.4679C>A p.P1560H | Missense Mutation (SNP) | VAF 64/266 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60297263; called by muse, mutect2, varscan2
- MAGEB2 | c.394G>T p.V132F | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV100975663, COSV66780301; called by muse, mutect2, varscan2
- MCM2 | c.2444G>A p.R815H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as rs779228557, COSV54035176; called by muse, mutect2, varscan2
- MEGF11 | c.793G>T p.G265W | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56545832; called by muse, mutect2, varscan2
- MOGAT3 | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs144059184, COSV56174757; called by muse, mutect2
- MTA2 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 31/520 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.57); catalogued as COSV53469962; called by muse, mutect2
- NBN | c.506G>C p.R169P | Missense Mutation (SNP) | VAF 97/573 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV55377376; called by muse, mutect2, varscan2
- NEXMIF | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 50/396 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as COSV50031276; called by muse, mutect2, varscan2
- NOS3 | c.1460del p.G487Afs*17 | Frame Shift Del (DEL) | VAF 39/187 reads (21%) | catalogued as COSV99871011, COSV99872196; called by mutect2, pindel, varscan2
- NPC1L1 | c.3499C>T p.L1167F | Missense Mutation (SNP) | VAF 90/620 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV56930736; called by muse, mutect2
- OLFML2B | c.1588G>T p.V530L | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV54193595; called by muse, mutect2, varscan2
- OR10A2 | c.739T>A p.F247I | Missense Mutation (SNP) | VAF 34/239 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); catalogued as COSV56299583; called by muse, mutect2, varscan2
- OR13C9 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV52240756; called by muse, mutect2
- OR1L4 | c.839C>T p.T280I | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52341233; called by muse, mutect2
- OR2T2 | c.47C>G p.T16R | Missense Mutation (SNP) | VAF 187/1598 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs760821810, COSV61618580; called by muse, mutect2, varscan2
- OR2T3 | c.578C>A p.S193Y | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62082723; called by muse, mutect2
- OR4X2 | c.776T>A p.I259K | Missense Mutation (SNP) | VAF 68/415 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.157); catalogued as COSV56584376; called by muse, mutect2, varscan2
- OR8G2P | c.60G>T p.Q20H | Missense Mutation (SNP) | VAF 46/278 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs1159134672; called by muse, varscan2
- PAXIP1 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 44/278 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1361943888; called by muse, varscan2
- PCDHA2 | c.1963G>T p.G655C | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65367281; called by muse, mutect2, varscan2
- PDE1C | c.95G>C p.R32P | Missense Mutation (SNP) | VAF 37/233 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58507644; called by muse, mutect2, varscan2
- PHRF1 | c.2732C>T p.A911V (on ENST00000264555 / NM_001286581.2; = p.A910V on NM_020901.4) | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV52754521; called by muse, mutect2, varscan2
- PNPLA3 | c.1070C>A p.P357H | Missense Mutation (SNP) | VAF 36/416 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs765749635; called by muse, mutect2
- POTEJ | c.2072G>T p.R691L | Missense Mutation (SNP) | VAF 103/674 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); catalogued as rs576615864; called by muse, mutect2, varscan2
- PRR23C | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1451507075; called by muse, mutect2, varscan2
- PRSS12 | c.1632G>A p.K544= | Splice Region (SNP) | VAF 66/654 reads (10%) | catalogued as rs1311989236, COSV99628678; called by muse, mutect2, varscan2
- PYHIN1 | c.1258C>G p.Q420E | Missense Mutation (SNP) | VAF 85/448 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV63721862; called by muse, mutect2, varscan2
- RALGDS | c.1663A>G p.K555E | Missense Mutation (SNP) | VAF 40/321 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs751495446; called by muse, mutect2, varscan2
- RANBP2 | c.3364A>T p.N1122Y | Missense Mutation (SNP) | VAF 103/819 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs749801208; called by muse, mutect2, varscan2
- RFPL4B | c.281G>T p.R94L | Missense Mutation (SNP) | VAF 60/258 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs747504146; called by muse, mutect2, varscan2
- RNF181 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 51/322 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.602); catalogued as COSV57818170; called by muse, mutect2, varscan2
- RPGR | c.118C>G p.L40V | Missense Mutation (SNP) | VAF 86/627 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.223); catalogued as COSV100140388; called by muse, mutect2, varscan2
- RYR2 | c.3091C>A p.R1031S | Missense Mutation (SNP) | VAF 37/265 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as COSV100771770; called by muse, mutect2, varscan2
- SALL4 | c.2732G>A p.G911D | Missense Mutation (SNP) | VAF 66/369 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as CM156281; called by muse, mutect2, varscan2
- SCN5A | c.1126C>A p.R376S | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.897); catalogued as CM140621; called by muse, mutect2, varscan2
- SERPINB3 | c.955G>A p.G319R | Missense Mutation (SNP) | VAF 49/347 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as rs577262694; called by muse, mutect2, varscan2
- SLITRK2 | c.137G>T p.C46F | Missense Mutation (SNP) | VAF 46/380 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59425233, COSV59426746; called by muse, mutect2, varscan2
- SNRNP200 | c.4423C>T p.R1475C | Missense Mutation (SNP) | VAF 107/569 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV60491708; called by muse, varscan2
- SPATA16 | c.676G>A p.V226M | Missense Mutation (SNP) | VAF 16/510 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs926855937; called by muse, mutect2
- SPTB | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 15/215 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779720812, COSV67635814; called by muse, mutect2
- SSTR4 | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV54796687, COSV99658529; called by muse, mutect2, varscan2
- STYXL2 | c.776G>T p.R259L | Missense Mutation (SNP) | VAF 42/276 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99609578; called by muse, mutect2, varscan2
- TBC1D2 | c.1485G>T p.K495N | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369354290; called by muse, mutect2
- TMEM132D | c.859G>T p.D287Y | Missense Mutation (SNP) | VAF 87/399 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101398941, COSV70598748; called by muse, mutect2, varscan2
- TOR1AIP1 | c.1384G>C p.D462H | Missense Mutation (SNP) | VAF 15/361 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV54870371; called by muse, mutect2
- TP53 | c.309C>G p.Y103* | Nonsense Mutation (SNP) | VAF 19/80 reads (24%) | catalogued as CM073388, COSV52663474, COSV52761478, COSV52776039, COSV53023378; called by muse, mutect2, varscan2
- TRIM67 | c.781G>T p.A261S | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.012); catalogued as COSV64158768, COSV64160809; called by muse, varscan2
- TRPM1 | c.187G>T p.G63C | Missense Mutation (SNP) | VAF 89/574 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs760064389; called by muse, mutect2, varscan2
- TRPS1 | c.1832G>T p.R611L (on ENST00000220888 / NM_001330599.2; = p.R624L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/362 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.953); catalogued as COSV99631206; called by muse, mutect2, varscan2
- TSPAN5 | c.235G>T p.G79W | Missense Mutation (SNP) | VAF 39/326 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59874890; called by muse, mutect2, varscan2
- UBE3A | c.131G>A p.C44Y | Missense Mutation (SNP) | VAF 51/242 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as CM971557; called by muse, mutect2, varscan2
- UPRT | c.562G>T p.G188C | Missense Mutation (SNP) | VAF 89/658 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100974563, COSV100974571, COSV64912752; called by muse, mutect2, varscan2
- USH2A | c.1079C>A p.T360K | Missense Mutation (SNP) | VAF 47/381 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV56451292; called by muse, mutect2, varscan2
- VCP | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 39/786 reads (5%) | catalogued as COSV62721939; called by muse, mutect2
- WWOX | c.1223G>T p.R408L | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs765857107, COSV68346099; called by muse, mutect2, varscan2
- ZNF518A | c.635G>T p.C212F | Missense Mutation (SNP) | VAF 68/433 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60153373; called by muse, mutect2, varscan2
- ZNFX1 | c.4360G>A p.E1454K | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.146); catalogued as rs769197106; called by muse, mutect2
- A2M | c.4020_4021insA p.F1341Ifs*13 | Frame Shift Ins (INS) | VAF 36/285 reads (13%) | called by mutect2, pindel, varscan2
- ABCA9 | c.2908A>G p.R970G | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- AC231657.3 | c.687G>T p.W229C | Missense Mutation (SNP) | VAF 66/308 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- ADD2 | c.968C>A p.A323D | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ADGRG4 | c.6518C>A p.P2173H | Missense Mutation (SNP) | VAF 83/527 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- ADH1C | c.390G>T p.R130S | Missense Mutation (SNP) | VAF 28/408 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AFF4 | c.1088-2A>G p.X363_splice | Splice Site (SNP) | VAF 32/177 reads (18%) | called by muse, mutect2, varscan2
- AGMO | c.332G>T p.W111L | Missense Mutation (SNP) | VAF 47/270 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- ANK2 | c.4631A>T p.E1544V | Missense Mutation (SNP) | VAF 32/316 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- ANO5 | c.478C>G p.R160G | Missense Mutation (SNP) | VAF 48/566 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.081); called by muse, mutect2
- APOB | c.7903G>A p.D2635N | Missense Mutation (SNP) | VAF 18/462 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2
- AREL1 | c.259G>C p.G87R | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); called by muse, mutect2
- ARHGAP31 | c.1006+1del | Frame Shift Del (DEL) | VAF 108/549 reads (20%) | called by mutect2, pindel, varscan2
- ARSF | c.1714T>C p.C572R | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ASRGL1 | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 44/338 reads (13%) | called by muse, mutect2, varscan2
- ATG7 | c.1225G>T p.G409C | Missense Mutation (SNP) | VAF 15/188 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ATPSCKMT | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 99/569 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- B3GALNT1 | c.100T>A p.W34R | Missense Mutation (SNP) | VAF 214/550 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BTBD7 | c.25C>A p.P9T | Missense Mutation (SNP) | VAF 44/547 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- C18orf21 | c.166C>G p.R56G | Missense Mutation (SNP) | VAF 105/882 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- C20orf194 | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 30/421 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.698); called by muse, mutect2
- CALHM1 | c.82G>T p.A28S | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- CAND2 | c.1163G>T p.R388L (on ENST00000456430 / NM_001162499.2; = p.R295L on NM_012298.3) | Missense Mutation (SNP) | VAF 52/262 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CCDC136 | c.1186C>G p.Q396E | Missense Mutation (SNP) | VAF 51/280 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CCDC178 | c.265G>T p.V89L | Missense Mutation (SNP) | VAF 60/361 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- CCKBR | c.432C>A p.S144R | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- CCT8L2 | c.1283G>A p.S428N | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CD1E | c.607T>A p.S203T | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, varscan2
- CDH8 | c.1288G>C p.D430H | Missense Mutation (SNP) | VAF 51/303 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CES5A | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 37/296 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- CGRRF1 | c.768G>T p.K256N | Missense Mutation (SNP) | VAF 63/592 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- COL25A1 | c.115G>C p.A39P | Missense Mutation (SNP) | VAF 20/243 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.043); called by muse, mutect2
- COL6A1 | c.1003G>T p.G335W | Missense Mutation (SNP) | VAF 55/275 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPA4 | c.818G>T p.C273F | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRACD | c.1916C>A p.P639H | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- CREB3L1 | c.634C>A p.H212N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRNKL1 | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- CUL9 | c.6847-5G>T | Splice Region (SNP) | VAF 22/198 reads (11%) | called by muse, mutect2
- CUL9 | c.6847-4C>T | Splice Region (SNP) | VAF 22/202 reads (11%) | called by muse, mutect2
- CWC22 | c.2375del p.S792Lfs*19 | Frame Shift Del (DEL) | VAF 46/436 reads (11%) | called by mutect2, pindel, varscan2
- CYP17A1 | c.562T>A p.Y188N | Missense Mutation (SNP) | VAF 62/668 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- DCC | c.848+2T>A p.X283_splice | Splice Site (SNP) | VAF 54/588 reads (9%) | called by muse, mutect2
- DCHS1 | c.670C>G p.Q224E | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.977); called by muse, mutect2
- DCP2 | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 80/405 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- DMBT1 | c.5413G>A p.V1805M (on ENST00000338354 / NM_001377530.1; = p.V1048M on NM_004406.3) | Missense Mutation (SNP) | VAF 107/573 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMRTA2 | c.701G>T p.R234L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.532); called by muse, mutect2
- DNHD1 | c.10390G>T p.D3464Y | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- DOCK10 | c.6287T>A p.L2096H | Missense Mutation (SNP) | VAF 38/282 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DPYD | c.1711G>T p.A571S | Missense Mutation (SNP) | VAF 83/528 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- EDA | c.287T>G p.L96R | Missense Mutation (SNP) | VAF 37/341 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- ENPP2 | c.1948A>G p.T650A (on ENST00000075322 / NM_001040092.3; = p.T702A on NM_006209.5) | Missense Mutation (SNP) | VAF 30/324 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- EPG5 | c.220G>T p.G74* | Nonsense Mutation (SNP) | VAF 29/376 reads (8%) | called by muse, mutect2
- EPS15L1 | c.994C>A p.Q332K | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERBB4 | c.3149A>G p.H1050R | Missense Mutation (SNP) | VAF 122/982 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ERICH3 | c.4429G>T p.G1477* | Nonsense Mutation (SNP) | VAF 47/339 reads (14%) | called by muse, mutect2, varscan2
- FAM133A | c.157dup p.T53Nfs*8 | Frame Shift Ins (INS) | VAF 50/346 reads (14%) | called by mutect2, varscan2
- FAM98A | c.1312C>T p.Q438* | Nonsense Mutation (SNP) | VAF 44/447 reads (10%) | called by muse, mutect2, varscan2
- FCGR3A | c.320-1G>T p.X107_splice | Splice Site (SNP) | VAF 16/286 reads (6%) | called by muse, mutect2
- FEZF1 | c.419A>G p.Q140R | Missense Mutation (SNP) | VAF 36/258 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FLT1 | c.3746T>C p.L1249P | Missense Mutation (SNP) | VAF 57/422 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- FRA10AC1 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 58/772 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- FRG2C | c.653T>C p.L218P | Missense Mutation (SNP) | VAF 36/544 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- FZD9 | c.1687C>A p.R563S | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRA4 | c.1304C>A p.P435Q | Missense Mutation (SNP) | VAF 53/414 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- GALNTL6 | c.422A>G p.N141S | Missense Mutation (SNP) | VAF 26/239 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- GATAD2A | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GFRA2 | c.1045+1G>T p.X349_splice | Splice Site (SNP) | VAF 34/400 reads (9%) | called by muse, mutect2
- GJA1 | c.857A>T p.Y286F | Missense Mutation (SNP) | VAF 151/707 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- GPC3 | c.898A>C p.I300L | Missense Mutation (SNP) | VAF 157/841 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- GPM6A | c.417G>T p.L139F | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRIK3 | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HYDIN | c.7321A>T p.S2441C | Missense Mutation (SNP) | VAF 14/281 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2
- ICE1 | c.4820A>C p.N1607T | Missense Mutation (SNP) | VAF 82/385 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- IFT140 | c.368G>C p.R123T | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.167); called by muse, mutect2
- INSM1 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IRAK1 | c.235C>A p.R79S | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- KARS1 | c.1100G>T p.G367V | Missense Mutation (SNP) | VAF 87/514 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KAT2B | c.1338G>T p.M446I | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNC2 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNC2 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 50/452 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- KCND2 | c.887G>T p.R296L | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNJ8 | c.775A>G p.I259V | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- KDM4D | c.695C>G p.P232R | Missense Mutation (SNP) | VAF 46/334 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- KIAA2013 | c.1870C>T p.P624S | Missense Mutation (SNP) | VAF 22/293 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.613); called by muse, mutect2
- KIF4A | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KLHL13 | c.886G>T p.V296L | Missense Mutation (SNP) | VAF 109/667 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- KRT35 | c.1160G>T p.R387L | Missense Mutation (SNP) | VAF 88/411 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- LAMB4 | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 18/307 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LARP7 | c.419G>T p.W140L | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LBP | c.1218-1G>T p.X406_splice | Splice Site (SNP) | VAF 17/130 reads (13%) | called by muse, mutect2, varscan2
- LRRC7 | c.3382C>T p.Q1128* (on ENST00000651989 / NM_001370785.2; = p.Q1095* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 42/246 reads (17%) | called by muse, varscan2
- LYN | c.1382G>C p.R461T | Missense Mutation (SNP) | VAF 40/440 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAGEB1 | c.632A>C p.K211T | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- MAP2K3 | c.898G>T p.D300Y (on ENST00000342679 / NM_145109.3; = p.D271Y on NM_002756.4) | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MARCHF10 | c.2113C>A p.L705I | Missense Mutation (SNP) | VAF 59/293 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MEX3D | c.586G>T p.G196C | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MMP2 | c.1316A>T p.K439M | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- MOCOS | c.1732del p.A578Pfs*23 | Frame Shift Del (DEL) | VAF 19/99 reads (19%) | called by mutect2, pindel, varscan2
- MXRA5 | c.6833G>A p.S2278N | Missense Mutation (SNP) | VAF 21/250 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.787); called by muse, mutect2
- MXRA5 | c.3055G>T p.E1019* | Nonsense Mutation (SNP) | VAF 31/164 reads (19%) | called by muse, mutect2, varscan2
- MYH13 | c.1433T>C p.L478P | Missense Mutation (SNP) | VAF 167/818 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MYLK | c.2050G>T p.E684* | Nonsense Mutation (SNP) | VAF 45/138 reads (33%) | called by muse, mutect2, varscan2
- MYLK3 | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- NAV3 | c.1390C>G p.Q464E | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- NBAS | c.6510G>T p.E2170D | Missense Mutation (SNP) | VAF 28/399 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.093); called by muse, mutect2
- NBPF12 | c.1537G>T p.V513L | Missense Mutation (SNP) | VAF 39/1255 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2
- NEGR1 | c.655G>T p.V219F | Missense Mutation (SNP) | VAF 61/466 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- NPC1L1 | c.3497T>C p.L1166P | Missense Mutation (SNP) | VAF 89/612 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- NPTXR | c.1305del p.T436Pfs*18 | Frame Shift Del (DEL) | VAF 31/157 reads (20%) | called by mutect2, pindel, varscan2
- OPCML | c.430G>T p.D144Y | Missense Mutation (SNP) | VAF 30/271 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- OR13G1 | c.442A>T p.I148F | Missense Mutation (SNP) | VAF 114/502 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- OR1S1 | c.761G>T p.C254F | Missense Mutation (SNP) | VAF 54/345 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR51A2 | c.220G>T p.G74C | Missense Mutation (SNP) | VAF 67/485 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- OR51A2 | c.219G>C p.L73F | Missense Mutation (SNP) | VAF 66/483 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- OR52A1 | c.568C>A p.L190I | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2
- OR52E8 | c.95G>T p.W32L | Missense Mutation (SNP) | VAF 42/409 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.228); called by muse, mutect2
- OR52R1 | c.103T>A p.C35S | Missense Mutation (SNP) | VAF 44/440 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- OR6C6 | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 62/412 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- OR8B2 | c.588G>T p.E196D | Missense Mutation (SNP) | VAF 46/359 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR8H1 | c.910A>T p.M304L | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR8U1 | c.748A>G p.I250V | Missense Mutation (SNP) | VAF 48/267 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR9A4 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 57/288 reads (20%) | SIFT tolerated (1); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- PARG | c.1150G>T p.A384S | Missense Mutation (SNP) | VAF 152/825 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCYT2 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 50/277 reads (18%) | called by muse, mutect2, varscan2
- PEAK1 | c.3411_3412insC p.G1138Rfs*42 | Frame Shift Ins (INS) | VAF 15/121 reads (12%) | called by mutect2, pindel, varscan2
- PEPD | c.934A>G p.S312G | Missense Mutation (SNP) | VAF 23/403 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.279); called by muse, mutect2
- PGAM2 | c.14G>T p.R5L | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- PIEZO2 | c.5676T>A p.D1892E | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- PITPNM1 | c.814G>T p.G272W | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- PKHD1L1 | c.7016G>C p.G2339A | Missense Mutation (SNP) | VAF 16/247 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- PODN | c.841C>T p.P281S (on ENST00000395871; = p.P233S on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- POF1B | c.1594T>C p.Y532H | Missense Mutation (SNP) | VAF 86/605 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- POLH | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 194/777 reads (25%) | called by muse, mutect2, varscan2
- POLM | c.1257G>T p.L419F | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- POLR3A | c.2865G>T p.K955N | Missense Mutation (SNP) | VAF 60/657 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.079); called by muse, mutect2
- PPP1R2 | c.135G>T p.Q45H | Missense Mutation (SNP) | VAF 117/360 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PPP1R3C | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 108/1172 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2
- PRPS2 | c.746C>A p.T249N | Missense Mutation (SNP) | VAF 68/300 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PRR15 | c.278G>T p.R93L | Missense Mutation (SNP) | VAF 41/218 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PSKH2 | c.698T>C p.V233A | Missense Mutation (SNP) | VAF 38/223 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- PTGIS | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 29/308 reads (9%) | called by muse, mutect2
- PTPRD | c.1780G>T p.G594C | Missense Mutation (SNP) | VAF 89/624 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRD | c.1541G>A p.G514E | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, varscan2
- PUM1 | c.2847G>T p.Q949H | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- RAD50 | c.312G>C p.Q104H | Missense Mutation (SNP) | VAF 29/447 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- RBMXL1 | c.731G>T p.R244L | Missense Mutation (SNP) | VAF 90/674 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- RET | c.697C>A p.Q233K | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RIMS2 | c.459T>A p.N153K | Missense Mutation (SNP) | VAF 63/411 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- RNF11 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 18/150 reads (12%) | called by muse, mutect2, varscan2
- RPS6KC1 | c.1810G>A p.D604N | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RTL4 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- RTL9 | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 74/339 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RTN1 | c.1739del p.P580Hfs*36 | Frame Shift Del (DEL) | VAF 18/88 reads (20%) | called by mutect2, pindel, varscan2
- SAMD9 | c.2634C>A p.N878K | Missense Mutation (SNP) | VAF 48/307 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- SASH3 | c.761C>A p.P254H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- SCAF8 | c.2999G>C p.R1000T | Missense Mutation (SNP) | VAF 63/296 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- SCN2A | c.3547C>A p.Q1183K | Missense Mutation (SNP) | VAF 70/894 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.014); called by muse, mutect2
- SETD1B | c.5716C>T p.H1906Y | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SFMBT2 | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 95/595 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SHROOM4 | c.40C>A p.Q14K | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- SHTN1 | c.518T>G p.V173G | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIRPB1 | c.640G>C p.V214L | Missense Mutation (SNP) | VAF 69/585 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SIRPB1 | c.464C>G p.P155R | Missense Mutation (SNP) | VAF 43/353 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- SKIDA1 | c.100A>C p.T34P | Missense Mutation (SNP) | VAF 21/240 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLITRK4 | c.1105A>T p.M369L | Missense Mutation (SNP) | VAF 52/477 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMC1A | c.1964G>T p.G655V | Missense Mutation (SNP) | VAF 105/506 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMC6 | c.2819G>T p.R940L | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2
- SPACA5B | c.299G>A p.C100Y | Missense Mutation (SNP) | VAF 74/1043 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- SPAG5 | c.2865G>T p.M955I | Missense Mutation (SNP) | VAF 61/321 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPATA16 | c.873G>T p.M291I | Missense Mutation (SNP) | VAF 48/1153 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- SPATA2 | c.1015A>T p.T339S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SPATA31A6 | c.160C>A p.P54T | Missense Mutation (SNP) | VAF 167/941 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- SPEN | c.7823A>T p.E2608V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SPHKAP | c.2940G>T p.K980N | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SRPX | c.422C>G p.S141C | Missense Mutation (SNP) | VAF 60/390 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STARD8 | c.1927C>A p.L643M | Missense Mutation (SNP) | VAF 48/291 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- STYXL2 | c.2485G>T p.D829Y | Missense Mutation (SNP) | VAF 17/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SYBU | c.238G>T p.G80C (on ENST00000276646 / NM_001099754.2; = p.G79C on NM_017786.6) | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SYCE2 | c.131G>A p.S44N | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.685); called by muse, mutect2
- TAF7L | c.937C>A p.H313N | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.096); called by muse, mutect2
- TAS2R41 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 87/448 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- TBC1D25 | c.1118T>C p.M373T | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TBC1D28 | c.175C>A p.R59S | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- TCP11L1 | c.137G>T p.S46I | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TENM1 | c.445A>T p.T149S | Missense Mutation (SNP) | VAF 66/333 reads (20%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TEX13C | c.2731C>A p.P911T | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- TFAP2B | c.486G>A p.M162I | Missense Mutation (SNP) | VAF 90/365 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- THADA | c.338A>T p.E113V | Missense Mutation (SNP) | VAF 34/436 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2
- TMEM232 | c.339A>T p.Q113H | Missense Mutation (SNP) | VAF 74/458 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM67 | c.1641G>C p.K547N | Missense Mutation (SNP) | VAF 49/1207 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- TRAPPC8 | c.1278G>C p.M426I | Missense Mutation (SNP) | VAF 29/245 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRPM6 | c.4641G>T p.E1547D | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.15); called by muse, mutect2
- TRPV2 | c.1351C>T p.L451= | Splice Region (SNP) | VAF 45/223 reads (20%) | called by muse, mutect2, varscan2
- TSNARE1 | c.1154A>G p.E385G | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- UBE2D2 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 23/481 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2
- UBQLNL | c.311A>T p.Q104L | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- UBR5 | c.2554A>T p.I852L | Missense Mutation (SNP) | VAF 82/551 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- UGT2B11 | c.1525A>G p.T509A | Missense Mutation (SNP) | VAF 64/555 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UNC79 | c.1418T>A p.L473Q (on ENST00000393151 / NM_001346218.2; = p.L296Q on NM_020818.5) | Missense Mutation (SNP) | VAF 57/485 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- USH2A | c.11246T>C p.L3749S | Missense Mutation (SNP) | VAF 89/714 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- USH2A | c.7263G>T p.L2421F | Missense Mutation (SNP) | VAF 98/436 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- USP20 | c.611G>T p.R204L | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- VGLL1 | c.100C>A p.Q34K | Missense Mutation (SNP) | VAF 71/408 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- VIP | c.267C>A p.D89E | Missense Mutation (SNP) | VAF 89/462 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- VPS13B | c.2727G>T p.W909C | Missense Mutation (SNP) | VAF 90/549 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VPS52 | c.1605G>C p.L535F | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- WDR17 | c.996A>T p.Q332H | Missense Mutation (SNP) | VAF 38/289 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2
- WDR87 | c.1950G>T p.M650I | Missense Mutation (SNP) | VAF 85/345 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- WIPF1 | c.262G>A p.G88S | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2
- WSCD2 | c.664C>G p.Q222E | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2
- ZFHX4 | c.6113del p.P2038Hfs*45 | Frame Shift Del (DEL) | VAF 22/220 reads (10%) | called by mutect2, pindel, varscan2
- ZNF282 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2
- ZNF496 | c.917A>G p.Q306R | Missense Mutation (SNP) | VAF 87/475 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ZNF592 | c.2911A>T p.R971W | Missense Mutation (SNP) | VAF 44/222 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- ZNF658 | c.650G>T p.C217F | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF727 | c.878T>A p.F293Y | Missense Mutation (SNP) | VAF 82/573 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, varscan2
- ADAMTSL2 | c.255C>A p.P85= | Silent (SNP) | VAF 52/378 reads (14%) | called by muse, mutect2, varscan2
- AFF2 | c.3039G>A p.T1013= | Silent (SNP) | VAF 180/862 reads (21%) | catalogued as rs781817593, COSV53987828; called by muse, mutect2, varscan2
- AMER1 | c.3219A>G p.P1073= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs1249947147; called by muse, mutect2, varscan2
- ATP2B2 | c.2667G>A p.T889= (on ENST00000352432; = p.T855= on NM_001683.5) | Silent (SNP) | VAF 23/143 reads (16%) | catalogued as rs779409545, COSV59490628; called by muse, mutect2, varscan2
- ATP6V1H | c.1143G>C p.V381= | Silent (SNP) | VAF 18/408 reads (4%) | called by muse, mutect2
- BCAN | c.2253C>A p.T751= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as rs148996313; called by muse, mutect2, varscan2
- C16orf90 | c.387T>G p.L129= (on ENST00000399645 / NM_001353385.2; = p.L120= on NM_001080524.2) | Silent (SNP) | VAF 30/350 reads (9%) | called by muse, mutect2
- CACNA1D | c.5676G>A p.E1892= (on ENST00000350061 / NM_001128840.3; = p.E1912= on NM_000720.4) | Silent (SNP) | VAF 24/157 reads (15%) | called by muse, mutect2, varscan2
- CAMSAP1 | c.1692C>T p.P564= | Silent (SNP) | VAF 24/238 reads (10%) | called by muse, mutect2, varscan2
- CCDC63 | c.765C>T p.L255= | Silent (SNP) | VAF 14/224 reads (6%) | called by muse, mutect2
- CCER2 | c.501G>A p.K167= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1171225720; called by muse, mutect2, varscan2
- CDH12 | c.1647G>A p.G549= | Silent (SNP) | VAF 21/220 reads (10%) | called by muse, mutect2
- CDNF | c.528C>T p.P176= | Silent (SNP) | VAF 18/221 reads (8%) | called by muse, mutect2
- CMSS1 | c.559T>C p.L187= | Silent (SNP) | VAF 101/427 reads (24%) | called by muse, mutect2, varscan2
- COL3A1 | c.2850T>A p.A950= | Silent (SNP) | VAF 111/676 reads (16%) | called by muse, mutect2, varscan2
- CPZ | c.1590C>T p.H530= (on ENST00000360986 / NM_001014447.3; = p.H519= on NM_003652.3) | Silent (SNP) | VAF 28/202 reads (14%) | catalogued as rs777682323; called by muse, mutect2, varscan2
- CTDP1 | c.441G>T p.T147= | Silent (SNP) | VAF 84/475 reads (18%) | catalogued as rs769613438, COSV50005017; called by muse, mutect2, varscan2
- CXCR3 | c.228C>G p.A76= | Silent (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2, varscan2
- DZIP1 | c.1359C>A p.P453= | Silent (SNP) | VAF 40/187 reads (21%) | called by muse, varscan2
- EEF1A1 | c.426A>G p.T142= | Silent (SNP) | VAF 42/390 reads (11%) | catalogued as rs1386102748; called by muse, mutect2, varscan2
- EIF2S3 | c.1062G>T p.V354= | Silent (SNP) | VAF 67/336 reads (20%) | called by muse, mutect2, varscan2
- EOLA1 | c.132T>C p.A44= | Silent (SNP) | VAF 16/354 reads (5%) | called by muse, mutect2
- FAM180A | c.393C>A p.A131= | Silent (SNP) | VAF 50/289 reads (17%) | called by muse, mutect2, varscan2
- FIGLA | c.258C>A p.A86= | Silent (SNP) | VAF 54/560 reads (10%) | called by muse, mutect2
- FUT6 | c.756C>A p.P252= | Silent (SNP) | VAF 44/287 reads (15%) | called by muse, mutect2, varscan2
- GAD2 | c.276C>T p.L92= | Silent (SNP) | VAF 6/73 reads (8%) | catalogued as rs1286344007, COSV52151246; called by muse, mutect2
- GLI3 | c.4413G>T p.G1471= | Silent (SNP) | VAF 243/1434 reads (17%) | catalogued as rs759881277, COSV67887997; called by muse, mutect2, varscan2
- GPR85 | c.12T>C p.Y4= | Silent (SNP) | VAF 16/140 reads (11%) | called by muse, mutect2, varscan2
- GRIPAP1 | c.1401C>G p.A467= | Silent (SNP) | VAF 33/415 reads (8%) | called by muse, mutect2
- HMCN2 | c.1245T>C p.S415= | Silent (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2
- IFI16 | c.873A>C p.P291= | Silent (SNP) | VAF 80/561 reads (14%) | called by muse, mutect2, varscan2
- IL9R | c.1248G>T p.T416= | Silent (SNP) | VAF 43/396 reads (11%) | called by muse, mutect2, varscan2
- JADE3 | c.2022T>A p.S674= | Silent (SNP) | VAF 17/170 reads (10%) | called by muse, mutect2, varscan2
- KIF1A | c.2826C>T p.R942= | Silent (SNP) | VAF 12/109 reads (11%) | called by muse, mutect2, varscan2
- KLHL4 | c.1284G>A p.V428= | Silent (SNP) | VAF 46/450 reads (10%) | called by muse, mutect2
- KMT5B | c.825C>T p.C275= | Silent (SNP) | VAF 17/191 reads (9%) | called by muse, mutect2
- KRT35 | c.1161G>T p.R387= | Silent (SNP) | VAF 84/403 reads (21%) | called by muse, mutect2, varscan2
- LAMC3 | c.3042G>A p.P1014= | Silent (SNP) | VAF 21/229 reads (9%) | catalogued as rs150155891; called by muse, mutect2
- LHFPL1 | c.522T>A p.G174= | Silent (SNP) | VAF 30/144 reads (21%) | called by muse, mutect2
- LILRB2 | c.87C>T p.P29= | Silent (SNP) | VAF 21/101 reads (21%) | called by muse, mutect2
- LRP1B | c.11226C>T p.C3742= | Silent (SNP) | VAF 62/601 reads (10%) | catalogued as rs373241949; called by muse, mutect2, varscan2
- LRRC7 | c.3444G>T p.A1148= (on ENST00000651989 / NM_001370785.2; = p.A1115= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 36/166 reads (22%) | catalogued as COSV50665907; called by muse, varscan2
- MAMLD1 | c.1380A>T p.P460= | Silent (SNP) | VAF 80/566 reads (14%) | called by muse, varscan2
- MAP2K3 | c.897G>T p.V299= (on ENST00000342679 / NM_145109.3; = p.V270= on NM_002756.4) | Silent (SNP) | VAF 32/169 reads (19%) | called by muse, mutect2, varscan2
- MCM4 | c.12G>T p.P4= | Silent (SNP) | VAF 25/173 reads (14%) | catalogued as rs1293460399; called by muse, mutect2, varscan2
- MME | c.87C>A p.I29= | Silent (SNP) | VAF 240/649 reads (37%) | catalogued as COSV100852413; called by muse, mutect2, varscan2
- MYH4 | c.657T>G p.L219= | Silent (SNP) | VAF 30/237 reads (13%) | called by muse, mutect2, varscan2
- MYH9 | c.66C>G p.A22= | Silent (SNP) | VAF 15/106 reads (14%) | called by muse, mutect2, varscan2
- MYO10 | c.3930G>T p.A1310= | Silent (SNP) | VAF 35/572 reads (6%) | called by muse, mutect2
- NAP1L2 | c.462C>A p.I154= | Silent (SNP) | VAF 74/454 reads (16%) | called by muse, mutect2, varscan2
- NUTM2G | c.765G>A p.E255= | Silent (SNP) | VAF 46/504 reads (9%) | called by muse, mutect2
- OPN3 | c.882G>T p.S294= | Silent (SNP) | VAF 199/718 reads (28%) | called by muse, mutect2, varscan2
- OR13C9 | c.798G>A p.E266= | Silent (SNP) | VAF 28/334 reads (8%) | catalogued as COSV52242572, COSV52242879; called by muse, mutect2
- OR2A2 | c.39G>T p.L13= | Silent (SNP) | VAF 25/155 reads (16%) | called by muse, mutect2, varscan2
- OR2T12 | c.540C>A p.P180= | Silent (SNP) | VAF 110/540 reads (20%) | catalogued as rs1478943719, COSV58776993, COSV58779415; called by muse, mutect2, varscan2
- OR4B1 | c.48C>T p.F16= | Silent (SNP) | VAF 22/188 reads (12%) | catalogued as COSV58884042; called by muse, varscan2
- OR51B6 | c.342T>A p.L114= | Silent (SNP) | VAF 22/264 reads (8%) | called by muse, mutect2
- OR6T1 | c.99G>A p.V33= | Silent (SNP) | VAF 26/527 reads (5%) | catalogued as rs1403515871, COSV100190278; called by muse, mutect2
- OR7C2 | c.732C>T p.L244= | Silent (SNP) | VAF 15/165 reads (9%) | catalogued as COSV50181038; called by muse, mutect2
- OTC | c.375G>T p.T125= | Silent (SNP) | VAF 114/698 reads (16%) | catalogued as COSV50003764; called by muse, mutect2, varscan2
- OTOG | c.4119G>A p.S1373= | Silent (SNP) | VAF 20/126 reads (16%) | catalogued as rs767688779; called by muse, mutect2, varscan2
- OXR1 | c.2014C>T p.L672= | Silent (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- PABPC3 | c.1215A>T p.T405= | Silent (SNP) | VAF 58/470 reads (12%) | called by muse, mutect2, varscan2
- PASD1 | c.987T>A p.V329= | Silent (SNP) | VAF 124/820 reads (15%) | called by muse, mutect2, varscan2
- PAXIP1 | c.1335G>A p.P445= | Silent (SNP) | VAF 48/282 reads (17%) | catalogued as rs61752010; called by muse, varscan2
- PCDHA5 | c.1110G>T p.L370= | Silent (SNP) | VAF 51/342 reads (15%) | called by muse, mutect2, varscan2
- PLPPR5 | c.285G>A p.R95= | Silent (SNP) | VAF 34/277 reads (12%) | called by muse, mutect2, varscan2
- PNPLA3 | c.1071C>A p.P357= | Silent (SNP) | VAF 34/408 reads (8%) | called by muse, mutect2
- PRDX4 | c.741T>G p.A247= | Silent (SNP) | VAF 42/336 reads (13%) | called by muse, mutect2, varscan2
- PRICKLE2 | c.891C>T p.P297= (on ENST00000295902; = p.P241= on NM_198859.4) | Silent (SNP) | VAF 67/328 reads (20%) | catalogued as rs774176459; called by muse, mutect2, varscan2
- PTGFR | c.543G>T p.A181= | Silent (SNP) | VAF 22/232 reads (9%) | catalogued as COSV66114459; called by muse, mutect2
- PTPN22 | c.2352G>A p.L784= (on ENST00000359785 / NM_001193431.2; = p.L729= on NM_012411.5) | Silent (SNP) | VAF 56/274 reads (20%) | catalogued as COSV100704053; called by muse, varscan2
- PTPN23 | c.4852C>A p.R1618= | Silent (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- RBM26 | c.666G>C p.L222= | Silent (SNP) | VAF 16/302 reads (5%) | called by muse, mutect2
- SIRT7 | c.48G>T p.R16= | Silent (SNP) | VAF 15/163 reads (9%) | called by muse, mutect2
- SLC4A7 | c.2715G>T p.L905= | Silent (SNP) | VAF 25/126 reads (20%) | called by muse, mutect2, varscan2
- SLFN13 | c.1758C>T p.S586= | Silent (SNP) | VAF 43/346 reads (12%) | catalogued as rs752329978; called by muse, mutect2, varscan2
- SMO | c.1785C>A p.S595= | Silent (SNP) | VAF 8/50 reads (16%) | called by mutect2, varscan2
- SP140 | c.2023C>T p.L675= | Silent (SNP) | VAF 42/428 reads (10%) | catalogued as rs1434166703; called by muse, mutect2, varscan2
- SP140L | c.696A>G p.Q232= | Silent (SNP) | VAF 71/444 reads (16%) | catalogued as rs1559449077; called by muse, mutect2, varscan2
- SPATA31A6 | c.1537C>T p.L513= | Silent (SNP) | VAF 128/873 reads (15%) | called by muse, mutect2, varscan2
- SVOP | c.1473G>T p.L491= | Silent (SNP) | VAF 47/209 reads (22%) | called by muse, mutect2, varscan2
- SVOP | c.996C>T p.Y332= | Silent (SNP) | VAF 31/241 reads (13%) | catalogued as rs755910712, COSV54463901; called by muse, mutect2, varscan2
- TAF1 | c.2007C>A p.P669= (on ENST00000373790 / NM_138923.4; = p.P690= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/695 reads (5%) | called by muse, mutect2
- TCF23 | c.99G>A p.K33= | Silent (SNP) | VAF 34/340 reads (10%) | called by muse, mutect2, varscan2
- TMEM212 | c.30G>T p.R10= | Silent (SNP) | VAF 128/336 reads (38%) | called by muse, mutect2, varscan2
- TRMT1L | c.1116A>G p.L372= | Silent (SNP) | VAF 31/226 reads (14%) | called by muse, mutect2, varscan2
- TSGA10IP | c.465A>T p.P155= | Silent (SNP) | VAF 21/144 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.23280A>G p.P7760= (on ENST00000591111; = p.P6833= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/66 reads (11%) | called by muse, varscan2
- WDR35 | c.2424C>T p.D808= (on ENST00000345530 / NM_001006657.2; = p.D797= on NM_020779.4) | Silent (SNP) | VAF 95/468 reads (20%) | called by muse, mutect2, varscan2
- WNT5A | c.927C>T p.C309= | Silent (SNP) | VAF 67/255 reads (26%) | catalogued as COSV52836178, COSV52838417; called by muse, mutect2, varscan2
- XKR6 | c.528G>T p.V176= | Silent (SNP) | VAF 41/321 reads (13%) | catalogued as COSV52009248; called by muse, mutect2, varscan2
- ZNF91 | c.1830A>T p.A610= | Silent (SNP) | VAF 64/518 reads (12%) | called by muse, mutect2, varscan2
- AC012485.1 | n.287G>T | RNA (SNP) | VAF 32/604 reads (5%) | catalogued as rs769364733; called by muse, mutect2
- ACSF3 | c.*1337C>T | 3'UTR (SNP) | VAF 41/190 reads (22%) | catalogued as rs1402006178; called by muse, mutect2, varscan2
- ADCYAP1 | chr18:904494 A>C | 5'Flank (SNP) | VAF 48/232 reads (21%) | called by muse, mutect2, varscan2
- AP002495.1 | c.*7A>T | 3'UTR (SNP) | VAF 24/186 reads (13%) | called by muse, mutect2, varscan2
- ARHGDIA | c.*119C>A | 3'UTR (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- ASIC4 | c.-48del | 5'UTR (DEL) | VAF 6/52 reads (12%) | called by mutect2, varscan2
- ATP6V1B1 | c.785+35T>A | Intron (SNP) | VAF 18/208 reads (9%) | called by muse, mutect2
- CACNA1B | c.530+9509C>A | Intron (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
- CCNDBP1 | c.-33G>C | 5'UTR (SNP) | VAF 17/274 reads (6%) | called by muse, mutect2
- CCNH | c.*10G>T | 3'UTR (SNP) | VAF 33/315 reads (10%) | called by muse, mutect2, varscan2
- CCT6A | c.1213+69G>A | Intron (SNP) | VAF 33/338 reads (10%) | called by muse, mutect2, varscan2
- CD8A | c.*268C>G | 3'UTR (SNP) | VAF 72/492 reads (15%) | called by muse, mutect2, varscan2
- CDH4 | c.170-24514G>T | Intron (SNP) | VAF 44/313 reads (14%) | called by muse, mutect2, varscan2
- CSAG2 | c.*6C>A | 3'UTR (SNP) | VAF 44/126 reads (35%) | called by mutect2, varscan2
- CSAG2 | c.*5C>A | 3'UTR (SNP) | VAF 44/125 reads (35%) | called by mutect2, varscan2
- CSNK1E | c.885+650G>T | Intron (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2
- CST9LP1 | n.80A>G | RNA (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- DHFR | c.-18G>C | 5'UTR (SNP) | VAF 41/285 reads (14%) | called by muse, mutect2, varscan2
- EGFLAM | c.-60G>A | 5'UTR (SNP) | VAF 9/115 reads (8%) | catalogued as rs1052116962; called by muse, mutect2
- EIF3E | c.206-24G>T | Intron (SNP) | VAF 73/594 reads (12%) | called by muse, mutect2, varscan2
- FCGR3B | c.-12C>T | 5'UTR (SNP) | VAF 94/531 reads (18%) | called by muse, mutect2, varscan2
- FHL1 | c.*968C>A | 3'UTR (SNP) | VAF 36/231 reads (16%) | called by muse, mutect2, varscan2
- GLB1L3 | c.1099+36G>A | Intron (SNP) | VAF 18/88 reads (20%) | called by muse, mutect2, varscan2
- GREM1 | c.-2+298G>T | Intron (SNP) | VAF 30/125 reads (24%) | called by muse, mutect2, varscan2
- HCST | c.110-11C>T | Intron (SNP) | VAF 17/208 reads (8%) | called by muse, mutect2
- ITGB3 | c.*23C>T | 3'UTR (SNP) | VAF 36/840 reads (4%) | called by muse, mutect2
- KCNN3 | c.-102G>T | 5'UTR (SNP) | VAF 36/446 reads (8%) | called by muse, mutect2
- KSR1 | c.1469-27G>T | Intron (SNP) | VAF 19/107 reads (18%) | called by muse, mutect2, varscan2
- MAGED1 | c.46-337C>A | Intron (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- MIR516A1 | n.8C>G | RNA (SNP) | VAF 26/333 reads (8%) | called by muse, mutect2
- NELL1 | c.1549+54747C>G | Intron (SNP) | VAF 9/95 reads (9%) | called by muse, mutect2
- NFE2L2 | chr2:177227860 del GTAATCCTA | 3'Flank (DEL) | VAF 32/264 reads (12%) | called by mutect2, pindel
- NMT1 | c.1332+197A>G | Intron (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- NOP53 | c.*10G>A | 3'UTR (SNP) | VAF 15/235 reads (6%) | called by muse, mutect2
- P3H4 | c.*45G>A | 3'UTR (SNP) | VAF 14/226 reads (6%) | catalogued as rs782341621, COSV62680205; called by muse, mutect2
- PCLO | c.13300+75C>T | Intron (SNP) | VAF 35/298 reads (12%) | catalogued as rs1461508672, COSV61649778; called by muse, mutect2, varscan2
- PCLO | c.13300+74T>C | Intron (SNP) | VAF 35/298 reads (12%) | called by muse, mutect2, varscan2
- PDLIM2 | c.-149C>T | 5'UTR (SNP) | VAF 8/48 reads (17%) | catalogued as rs748827218; called by muse, mutect2, varscan2
- PHACTR1 | c.104-158T>A | Intron (SNP) | VAF 20/240 reads (8%) | called by muse, mutect2
- PMPCB | c.99+98del | Intron (DEL) | VAF 18/154 reads (12%) | called by mutect2, pindel, varscan2
- RIMS2 | c.3821+1018G>T | Intron (SNP) | VAF 55/361 reads (15%) | called by muse, mutect2, varscan2
- RPSA | c.498+111G>T | Intron (SNP) | VAF 34/527 reads (6%) | called by muse, mutect2
- SF1 | c.*350C>T | 3'UTR (SNP) | VAF 15/96 reads (16%) | catalogued as rs766299778; called by muse, mutect2, varscan2
- SLC2A14 | chr12:7892711 C>T | 5'Flank (SNP) | VAF 20/242 reads (8%) | catalogued as rs772654303; called by muse, mutect2
- SNORD114-18 | n.63T>A | RNA (SNP) | VAF 25/238 reads (11%) | called by muse, mutect2
- SNORD115-4 | n.33A>G | RNA (SNP) | VAF 113/587 reads (19%) | called by muse, mutect2, varscan2
- SPTA1 | c.6530+24C>T | Intron (SNP) | VAF 163/713 reads (23%) | called by muse, mutect2, varscan2
- TBC1D10A | c.-16G>T | 5'UTR (SNP) | VAF 11/71 reads (15%) | catalogued as rs944735959; called by muse, mutect2, varscan2
- TFAP2E | c.-17C>A | 5'UTR (SNP) | VAF 13/120 reads (11%) | called by muse, mutect2, varscan2
- TMCO1 | c.223+9G>A | Intron (SNP) | VAF 56/370 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.10360+3511G>A | Intron (SNP) | VAF 35/211 reads (17%) | called by muse, mutect2, varscan2
- U82695.1 | n.1869C>T | RNA (SNP) | VAF 10/146 reads (7%) | catalogued as rs782403642, COSV100931058; called by muse, mutect2
- UBE2D3 | c.120+12G>A | Intron (SNP) | VAF 43/404 reads (11%) | catalogued as COSV57660356; called by muse, mutect2, varscan2
- VAMP7 | c.-2C>A | 5'UTR (SNP) | VAF 40/248 reads (16%) | called by muse, mutect2, varscan2
- VAMP7 | c.-1C>A | 5'UTR (SNP) | VAF 40/251 reads (16%) | called by muse, mutect2, varscan2
- WASF4P | n.411C>A | RNA (SNP) | VAF 115/583 reads (20%) | called by muse, mutect2, varscan2
- ZNF41 | chrX:47483785 C>G | 5'Flank (SNP) | VAF 46/352 reads (13%) | called by muse, mutect2, varscan2
- ZNF449 | c.354+111C>A | Intron (SNP) | VAF 28/137 reads (20%) | called by muse, mutect2, varscan2
